Somatic mutation profile of tumor specimen 0DFBLS from CCDI case PBBRZV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Bone, NOS; Age at diagnosis: 3.3 years (1,211 days).
Specimen 0DFBLS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 272d2c97-a160-41fe-ace6-26ffddb36375.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFBL9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/661292c7-655f-4e63-b07e-f50023ecb062

The open-access MAF lists 20 somatic variants for this specimen: 9 protein-altering or splice-affecting, 5 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Intron 5, Silent 5, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ENOX2 | c.486G>T p.K162N (on ENST00000338144 / NM_001382520.1; = p.K133N on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/422 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100584021; called by muse, varscan2
- GK | c.1436G>A p.S479N (on ENST00000427190 / NM_001205019.2; = p.S473N on NM_000167.6) | Missense Mutation (SNP) | VAF 36/318 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as rs1569176578; called by muse, varscan2
- GRIA3 | c.2393G>T p.W798L | Missense Mutation (SNP) | VAF 52/347 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1187634131; called by muse, varscan2
- MST1 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 50/387 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757815409, COSV99610857; called by muse, varscan2
- RIMBP2 | c.1720G>A p.V574M | Missense Mutation (SNP) | VAF 54/464 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs200419075, COSV55470298; called by muse, varscan2
- SPTAN1 | c.761C>A p.A254E | Missense Mutation (SNP) | VAF 36/321 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs794727784; ClinVar: uncertain significance; called by muse, varscan2
- NAF1 | c.163C>A p.Q55K | Missense Mutation (SNP) | VAF 32/262 reads (12%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); called by muse, varscan2
- NUP205 | c.5513G>T p.S1838I | Missense Mutation (SNP) | VAF 163/607 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.009); called by muse, varscan2
- PAQR8 | c.886C>A p.Q296K | Missense Mutation (SNP) | VAF 42/232 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- DCAF8L1 | c.861A>C p.G287= | Silent (SNP) | VAF 44/292 reads (15%) | called by muse, varscan2
- DKC1 | c.672C>A p.T224= | Silent (SNP) | VAF 76/619 reads (12%) | called by muse, varscan2
- PLA2G6 | c.2409G>T p.L803= | Silent (SNP) | VAF 60/322 reads (19%) | called by muse, varscan2
- TAB3 | c.1977A>T p.A659= | Silent (SNP) | VAF 42/277 reads (15%) | called by muse, varscan2
- VSIG4 | c.342A>G p.E114= | Silent (SNP) | VAF 40/296 reads (14%) | catalogued as COSV66074928; called by muse, varscan2
- ASIC2 | c.556-179448G>C | Intron (SNP) | VAF 28/208 reads (13%) | called by muse, varscan2
- CCDC149 | c.63+17714C>A | Intron (SNP) | VAF 19/182 reads (10%) | catalogued as rs1341369251; called by muse, varscan2
- CCDC149 | c.63+17713T>G | Intron (SNP) | VAF 19/183 reads (10%) | called by muse, varscan2
- EEF1AKMT2 | c.292-25A>T | Intron (SNP) | VAF 10/76 reads (13%) | called by muse, varscan2
- NSFL1C | c.786-60T>A | Intron (SNP) | VAF 8/68 reads (12%) | called by muse, varscan2
- OR2AP1 | c.*96A>G | 3'UTR (SNP) | VAF 4/40 reads (10%) | catalogued as rs1012935800, COSV58726711; called by muse, varscan2
